Gene-level copy-number profile of tumor specimen TCGA-D3-A2J9-06A from TCGA case TCGA-D3-A2J9, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 75.3 years (27,508 days).
Specimen TCGA-D3-A2J9-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.a84ac346-6e22-4670-a846-77453745cdc7.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D3-A2J9-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3f39c064-12bb-4027-8b9e-f7d71648b465

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 90; copy number 1: 3,378; copy number 2: 44,779; copy number 3: 8,387; copy number 4: 2,950; copy number 5: 226.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D3-A2J9-06A-11D-A194-01): tumor purity 0.2, ploidy 2.33, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 90 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:21,903,077–22,518,871, 90 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 226 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:45,573,346–50,049,929, 65 genes, copy number 5 (broad region; genes not listed).
- chr6:54,190,206–63,779,336, 80 genes, copy number 5 (broad region; genes not listed).
- chr6:63,797,189–63,857,769, 3 genes, copy number 5: AL354719.1, SCAT8, GCNT1P4.
- chr15:52,755,053–54,633,414, 15 genes, copy number 5 (within-gene range 4–5): ONECUT1, AC016044.1, RPSAP55, EEF1A1P22, LINC02490, AC066614.1, WDR72, RNU2-53P, RNU6-449P, AC084759.1, AC084759.3, AC084759.2, UNC13C, AC010867.1, HNRNPA1P74.
- chr15:94,724,928–98,320,237, 63 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 992. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
